Somatic mutation profile of tumor specimen 0D97WG from CCDI case PBBIJK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.9 years (1,786 days).
Specimen 0D97WG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ca5a6ac-e6fb-4478-817d-58336a589869.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D97WH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0181066b-bcf6-4f8a-babc-063fb421bd5f

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, 5'UTR 2, Nonsense Mutation 2, Intron 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GLE1 | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 165/447 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs748516029; called by muse, mutect2, varscan2
- HIP1R | c.2559+4del | Splice Region (DEL) | VAF 40/292 reads (14%) | catalogued as rs781122702; called by mutect2, varscan2
- KANK4 | c.14A>G p.D5G | Missense Mutation (SNP) | VAF 191/452 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1329889211; called by muse, mutect2, varscan2
- LRPPRC | c.3338C>G p.T1113R | Missense Mutation (SNP) | VAF 160/442 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs751680548, COSV53233470, COSV99581488; called by muse, varscan2
- RMC1 | c.1855C>T p.R619* | Nonsense Mutation (SNP) | VAF 129/309 reads (42%) | catalogued as rs1354688245, COSV52574934; called by muse, mutect2, varscan2
- SPRED3 | c.503C>G p.T168R | Missense Mutation (SNP) | VAF 96/225 reads (43%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.92); catalogued as rs770870676; called by muse, mutect2, varscan2
- AMOT | c.1193A>C p.Q398P | Missense Mutation (SNP) | VAF 244/277 reads (88%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- C9 | c.807T>A p.S269R | Missense Mutation (SNP) | VAF 201/524 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- LOXL2 | c.1414G>T p.E472* | Nonsense Mutation (SNP) | VAF 141/322 reads (44%) | called by muse, mutect2, varscan2
- OTX2 | c.206A>T p.E69V (on ENST00000408990 / NM_172337.3; = p.E77V on NM_021728.4) | Missense Mutation (SNP) | VAF 201/687 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- THPO | c.514G>T p.V172F (on ENST00000649095 / NM_001290003.1; = p.V32F on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 223/556 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); called by muse, mutect2, varscan2
- MPP6 | c.*41del | 3'UTR (DEL) | VAF 47/88 reads (53%) | catalogued as rs1313516162; called by mutect2, varscan2
- NDUFA3 | c.-19C>G | 5'UTR (SNP) | VAF 133/313 reads (42%) | called by muse, mutect2, varscan2
- TTN | c.34522+878A>T | Intron (SNP) | VAF 310/864 reads (36%) | called by muse, mutect2, varscan2
- ZNF273 | c.-24T>G | 5'UTR (SNP) | VAF 57/130 reads (44%) | called by muse, mutect2, varscan2
